Surgical pathology report (de-identified scan), TCGA case TCGA-5V-A9RR, project TCGA-THYM (Thymoma), tissue source site Roswell Park, specimen TCGA-5V-A9RR-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Thymoma, type AB NOS 8582/1
Site Thymus C379
JW3/10/14

Surg Date

SPECIMENS:

- A. THYMUS
- B. CERVICAL HORN

SPECIMEN(S):

- A. THYMUS
- B. CERVICAL HORN

DIAGNOSIS:

- A. THYMUS, THYMECTOMY:
- ENCAPSULATED THYMOMA (8 CM), TYPE AB.
- RESECTION MARGINS ARE NEGATIVE BUT CLOSE.
- ADJACENT BENIGN INVOLUTED THYMIC TISSUE.
- B. "CERVICAL HORN", EXCISION:
- BENIGN FIBROADIPOSE TISSUE AND INVOLUTED THYMIC TISSUE.

SYNOPTIC REPORT - MEDIASTINUM & THYMUS

Specimens Involved

Specimens: A: THYMUS

Specimen Type: Cervical thymectomy
Specimen Size: Greatest dimension: 10.5cm
Additional dimensions: 5cm x 3.8cm
Tumor Site: Thymus
Tumor Size: Greatest dimension: 8cm
Additional dimensions: 4.8cm x 3cm
WHO CLASSIFICATION
Thymoma 8580/1
Type AB (mixed) 8582/1
Extent of Invasion: Stage I: Grossly and microscopically encapsulated
Margins: Margins uninvolved by tumor
Distance of tumor from closest margin: 0.1cm
Specific margin: Soft tissue margin
Angiolymphatic Invasion: Absent
Additional Pathologic Findings: None identified
Lymph nodes: No lymph nodes sampled
Regional Lymph Nodes: Cannot be assessed
Distant Metastasis: Cannot be assessed

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A6

Population: Tumor Cells

Stain/Marker: Result: Comment:

CYTOKERATIN 5/6 Positive

CD5 Positive Weak, focal; high background, mostly T cells

CD4 Negative Immature lymphocytes

CD8 Negative Immature lymphocytes

CD 3 Negative Immature lymphocytes

TdT Negative Immature lymphocytes

CD1A Negative Immature lymphocytes

MIB1-Ki67 Positive 50-60%

CD31 Negative No lymphovascular invasion seen

CD 20, L26 Negative Sparse B cells

RETICULIN STAIN Positive Perinodular pattern mainly

[page 2 of 2]
Surg Date

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

GROSS DESCRIPTION:**A. THYMUS**

Received fresh labeled with the patient's identification and designated "thymus" is an oriented, intact thymectomy specimen with attached adipose tissue weighing 110 g and measuring 10.5 x 5 x 3.8 cm. A suture marks superior portion. Ink code: Superior-blue, remainder of the specimen-black. The specimen is serially sectioned from superior to inferior to reveal an encapsulated, pink-tan mass, with homogeneous, fleshy/lobulated cut surface and focal areas of white, fibrous septae, 8 x 4.8 x 3 cm, located superior/mid/inferior, grossly confined to the capsule. Gross photograph is taken. A portion of the specimen is submitted for flow cytometry, cytogenetics, and tissue procurement. Representative sections are submitted:

A1-A3: Perpendicular sections, mass, superior

A4-A9: Mass, mid

A10-A11: Mass, inferior

A12: Random sections attached adipose tissue

B. CERVICAL HORN

Received in formalin labeled with the patient's identification and designated "cervical horn" are two fragments of yellow-tan adipose tissue 2 x 1.2 x 0.5 cm (demonstrating unidentified suture) and 1.1 x 0.8 x 0.4 cm. The larger fragment with suture inked blue. The entire specimen submitted:

B1: Larger fragment

B2: Smaller fragment

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

None Given

Gross Dictation:,

Microscopic/Diagnostic Dictation:, ,

Final Review:, M.D., PATHOLOGIST,

Final:, M.D., PATHOLOGIST,

Source: NCI Genomic Data Commons file ec51fd08-9a94-48fa-b2f0-f5755e3f9755 (TCGA-5V-A9RR.4D439581-C988-4DA5-A4B2-AAA04BE72975.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).